Somatic mutation profile of tumor specimen TCGA-BF-AAP6-01A (aliquot TCGA-BF-AAP6-01A-11D-A401-08) from TCGA case TCGA-BF-AAP6, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Epithelioid cell melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 55.8 years (20,384 days).
Specimen TCGA-BF-AAP6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c39430f0-38c1-4f83-9d35-ba3cff783f01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BF-AAP6-10A (Blood Derived Normal), aliquot TCGA-BF-AAP6-10A-01D-A401-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16c00630-1212-4803-910c-44631e333fbd

The open-access MAF lists 77 somatic variants for this specimen: 54 protein-altering or splice-affecting, 22 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 22, Splice Region 1, Intron 1, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/93 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ALPK3 | c.4880G>A p.G1627D | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV99360527; called by muse, mutect2, varscan2
- AMY2B | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 110/303 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs144281226; called by muse, mutect2, varscan2
- ASPHD2 | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); catalogued as COSV99313222; called by muse, mutect2, varscan2
- ATG7 | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 4/69 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.437); catalogued as COSV100607010; called by muse, mutect2
- CCDC83 | c.485T>C p.V162A | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV99721572; called by muse, mutect2, varscan2
- CLEC1A | c.776G>A p.R259K | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.01); catalogued as rs753671101, COSV100191272; called by muse, mutect2, varscan2
- COL11A1 | c.4814G>A p.R1605Q | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs371100196; called by muse, mutect2, varscan2
- COL9A2 | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101025634; called by muse, mutect2, varscan2
- CX3CR1 | c.1063C>T p.L355F | Missense Mutation (SNP) | VAF 60/144 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.459); catalogued as COSV100843162; called by muse, mutect2, varscan2
- DAG1 | c.2426C>T p.P809L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100444796; called by muse, mutect2, varscan2
- DNAJB6 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs1412871114, COSV51095770; called by muse, mutect2, varscan2
- EPHA2 | c.1125A>T p.E375D | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100626052; called by muse, mutect2, varscan2
- ERG | c.1315G>A p.A439T (on ENST00000398919 / NM_001243428.1; = p.A415T on NM_004449.4) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99901508; called by muse, mutect2, varscan2
- ETS2 | c.397G>T p.G133C | Missense Mutation (SNP) | VAF 44/117 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.033); catalogued as COSV100711239; called by muse, mutect2, varscan2
- F5 | c.6087G>T p.E2029D | Missense Mutation (SNP) | VAF 44/62 reads (71%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as rs549481773, COSV100889015; called by muse, mutect2, varscan2
- GOLIM4 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV100462817; called by muse, mutect2, varscan2
- GTF2F1 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT tolerated (0.64); PolyPhen benign (0.121); catalogued as rs1321453303, COSV101081122; called by muse, mutect2, varscan2
- GUCA1C | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53751486, COSV99659838; called by muse, mutect2
- IBSP | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.082); catalogued as rs748954490, COSV56894710, COSV56896288; called by muse, mutect2, varscan2
- KDM4A | c.2593G>C p.G865R | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100969421, COSV64959613; called by muse, mutect2, varscan2
- KDM4A | c.2594G>A p.G865D | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100969422; called by muse, mutect2, varscan2
- KLHDC3 | c.327C>G p.D109E | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV99763631; called by muse, mutect2, varscan2
- LAMA5 | c.8318C>T p.P2773L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.04); catalogued as COSV99438867; called by muse, mutect2, varscan2
- LCMT1 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.123); catalogued as rs955529636, COSV66727780; called by muse, mutect2
- MCTP1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.963); catalogued as COSV100386680; called by muse, mutect2, varscan2
- MKS1 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.391); catalogued as COSV100439526; called by muse, mutect2, varscan2
- MORC1 | c.41G>A p.R14H | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs759790452, COSV51713109; called by muse, mutect2, varscan2
- MYBPC1 | c.775G>A p.D259N (on ENST00000550270 / NM_206820.2; = p.D284N on NM_002465.4) | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100637849; called by muse, mutect2, varscan2
- MYH3 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1160002369, COSV56864439; called by muse, mutect2, varscan2
- NOTCH4 | c.2336G>A p.G779E | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100900541, COSV66682808; called by muse, mutect2, varscan2
- NPNT | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 41/98 reads (42%) | catalogued as rs371895067; called by muse, mutect2, varscan2
- OR2A2 | c.61G>C p.A21P | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV101286635; called by muse, mutect2
- OR4D2 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs370339516; called by muse, mutect2, varscan2
- OTOS | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100108807; called by muse, mutect2, varscan2
- PIGM | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100928016; called by muse, mutect2, varscan2
- PPARGC1B | c.2413C>T p.L805F | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as rs768108478, COSV100494599; called by muse, mutect2, varscan2
- PRICKLE1 | c.704G>A p.G235D | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV100566182; called by muse, mutect2, varscan2
- PRKCH | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.822); catalogued as rs748623872, COSV60646188; called by muse, mutect2, varscan2
- PTEN | c.724del p.E242Sfs*14 | Frame Shift Del (DEL) | VAF 34/62 reads (55%) | catalogued as COSV64291584, COSV64299810; called by mutect2, pindel, varscan2
- PTPA | c.1057C>T p.H353Y (on ENST00000337738 / NM_178001.2; = p.H318Y on NM_021131.5) | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV100533972; called by muse, mutect2
- RASGRP3 | c.1849G>A p.E617K (on ENST00000402538 / NM_001349975.2; = p.E616K on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV101274719; called by muse, mutect2, varscan2
- RPE65 | c.544C>A p.H182N | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs61752884, CM040791, CM983762, COSV99253732; ClinVar: not provided; called by muse, mutect2, varscan2
- SCN10A | c.1856C>T p.S619F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101479307, COSV71862334; called by muse, mutect2, varscan2
- SCN3A | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142323631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC26A5 | c.898G>A p.G300R | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV59701896, COSV59703331; called by muse, mutect2, varscan2
- SLC41A2 | c.1597G>A p.D533N | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs750412859, COSV99316299; called by muse, mutect2, varscan2
- SMPD3 | c.1261C>T p.H421Y | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.41); catalogued as COSV99545470; called by muse, mutect2, varscan2
- TENM1 | c.5944C>T p.L1982F | Missense Mutation (SNP) | VAF 84/100 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV100949508; called by muse, mutect2, varscan2
- TIAM1 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753525414, COSV54552084; called by muse, mutect2, varscan2
- TMEM52 | c.351C>T p.S117= | Splice Region (SNP) | VAF 14/31 reads (45%) | catalogued as rs775553355, COSV57071398; called by muse, mutect2, varscan2
- URGCP | c.175G>A p.E59K (on ENST00000453200 / NM_001077663.3; = p.E50K on NM_017920.4) | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV56247122, COSV99787092; called by muse, mutect2, varscan2
- ZCCHC2 | c.3317G>A p.R1106K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV54041099; called by muse, mutect2, varscan2
- ZNF484 | c.734A>G p.H245R | Missense Mutation (SNP) | VAF 54/72 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100214542; called by muse, mutect2, varscan2
- ADCY4 | c.915C>T p.F305= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as rs772375376, COSV53476905; called by muse, mutect2, varscan2
- AMPH | c.1644C>T p.A548= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs766340009, COSV100341486; called by muse, mutect2, varscan2
- CPED1 | c.2836C>T p.L946= | Silent (SNP) | VAF 72/126 reads (57%) | catalogued as COSV100120367, COSV59997549; called by muse, mutect2, varscan2
- CYP2A13 | c.795G>A p.R265= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV57838034; called by muse, mutect2, varscan2
- DNAH3 | c.8124C>T p.I2708= | Silent (SNP) | VAF 54/133 reads (41%) | catalogued as rs377341386, COSV99765941; called by muse, mutect2, varscan2
- HCN1 | c.1140C>T p.I380= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as rs756675765, COSV57490916; called by muse, mutect2, varscan2
- INSM2 | c.954G>A p.A318= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99353997; called by muse, mutect2, varscan2
- KCNA1 | c.732C>A p.P244= | Silent (SNP) | VAF 31/69 reads (45%) | catalogued as COSV101230170; called by muse, mutect2, varscan2
- MMP3 | c.1059C>T p.F353= | Silent (SNP) | VAF 62/109 reads (57%) | catalogued as COSV100242743; called by muse, mutect2, varscan2
- N4BP3 | c.1167G>A p.A389= | Silent (SNP) | VAF 45/63 reads (71%) | catalogued as rs1235509090, COSV51066877; called by muse, mutect2, varscan2
- NPAS1 | c.1410G>A p.R470= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs1421994357, COSV53409094; called by muse, mutect2, varscan2
- NT5DC3 | c.279G>C p.L93= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV101230914; called by muse, mutect2, varscan2
- P2RY10 | c.474C>T p.I158= | Silent (SNP) | VAF 33/40 reads (83%) | catalogued as rs1340508456, COSV50680337; called by muse, mutect2, varscan2
- PRKCH | c.444C>T p.D148= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as rs1350216047, COSV100273027; called by muse, mutect2, varscan2
- RGS16 | c.240C>T p.H80= | Silent (SNP) | VAF 137/196 reads (70%) | catalogued as rs143272517; called by muse, mutect2, varscan2
- SCN8A | c.474G>A p.S158= | Silent (SNP) | VAF 15/29 reads (52%) | catalogued as rs374989727; ClinVar: likely benign; called by muse, mutect2, varscan2
- SEMG2 | c.1269G>A p.K423= | Silent (SNP) | VAF 51/82 reads (62%) | catalogued as COSV65647598, COSV65647955; called by muse, mutect2, varscan2
- TANC1 | c.3000G>A p.K1000= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs565672082, COSV99713401; called by muse, mutect2, varscan2
- TMEM120B | c.183C>T p.L61= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100699621; called by muse, mutect2
- TTN | c.70908C>T p.F23636= (on ENST00000591111; = p.F16212= on NM_003319.4) | Silent (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100602162; called by muse, mutect2, varscan2
- ZBBX | c.1389C>T p.S463= | Silent (SNP) | VAF 79/209 reads (38%) | catalogued as COSV100283578; called by muse, mutect2, varscan2
- ZNF781 | c.519G>A p.L173= | Silent (SNP) | VAF 38/85 reads (45%) | catalogued as COSV62202942; called by muse, mutect2, varscan2
- ARHGEF4 | c.1921+22C>T | Intron (SNP) | VAF 16/30 reads (53%) | catalogued as COSV100387803; called by muse, mutect2, varscan2
